CCDI case PBCSKM — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS.
https://portal.gdc.cancer.gov/cases/3a82b57b-873c-490a-ab1c-b3b276daf692

Demographics
Sex at birth: male.

Diagnoses (1)
1. Neuroblastoma, NOS: ICD-O-3 morphology code: 9500/3; Tissue or organ of origin: Abdomen, NOS; Age at diagnosis: 1.8 years (657 days).

Biospecimens (2 samples)
- Sample 0DYC3D: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DYC3K: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
